Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A6QS, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A6QS-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: There is an esophagus fragment up to 9 x 5 cm in its size, with a grey-white tumor up to 6.5 cm in its size, with superficial ulceration.

Microscopic Description: Squamous cell carcinoma of the esophagus, keratinizing sub-type, G-1 (pT2), with ulceration. Two paraesophageal lymph nodes were examined. One of them demonstrated metastasis. Another one demonstrated lipomatosis. Eight lymph nodes along the a. gastrica sinistrae were examined. One of them demonstrated metastasis. All other lymph nodes demonstrated anthracosis, follicular hyperplasia.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Muscularis Propria, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Esophagus

Tumor size: 0 x 0 x 6.5 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Well differentiated

Tumor extent: Muscularis propria

Lymph nodes: 2/10 positive for metastasis (Paraesophageal (2), along the a. gastrica sinistra 2/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: tumor location; lower third of esophagus. tumor features: ulcerated

Comments: None

ICD-O-3

Carcinoma, squamous cell
keratinizing 807113

Site Distal third of
esophagus C15.5

7/5/13

For Malignancy History		✓

Source: NCI Genomic Data Commons file f6034f59-dacf-4a35-8b06-3e53c5aaa2c8 (TCGA-IG-A6QS.02D2F724-69E1-4BA7-A9C2-5406BA92536F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).